Surgical pathology report (de-identified scan), TCGA case TCGA-EE-A182, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site University of Sydney, specimen TCGA-EE-A182-06A (Metastatic).

[page 1 of 2]
12/19/10
lu

ICB-0-3

Melanoma, NOS 8720/3

Site Code: Thigh, subcutaneous
years Female tissue C49.2

DOB/Age/Sex:
Location:
Requested by:
Requested on:
Specimen Rcvd:
Accession No.:
Copies to:

HISTOPATHOLOGY REPORT

CLINICAL DETAILS

Metastatic melanoma.

(1) Left thigh, left axilla, left arm.

MACROSCOPIC DESCRIPTION

Three specimens were received.

1. "TUMOUR FROM LEFT THIGH". Specimen received fresh for tumour banking, and consists of an ellipse of skin 63 x 42 x 10mm with subcutis to a depth of 10mm. On the surface centrally is a pigmented, markedly exophytic nodule 65 x 45mm. Margins inked blue. One-third of nodule taken for tumour banking. Cut surface shows that the entire nodule has a dark brown/black appearance, and comes close to but appears just clear of the peripheral margins, and appears clear of the poles. The tumour nodule extends 26mm in depth, and comes within 2mm of the deep inked blue margin.

A-B. Full face of tumour nodule (A includes tumour to closest deep and lateral margin).

2. "TUMOUR FROM LEFT AXILLA". Specimen received fresh for tumour banking. Two separate ellipses of skin, the larger 55 x 40 x 20mm with a nodule 48 x 44mm, whereas the smaller measures 30 x 11mm, with a subcutaneous nodule 35mm. Margins inked blue. Half of nodule submitted for tumour banking (). Cut surface of the smaller nodule shows that it is circumscribed, however essentially abuts the deep and lateral margins. Cut surface of the larger nodule shows that it essentially abuts the lateral margin, and comes close to the deep margin.

A-B. Transverse section of smaller nodule showing tumour to closest margins bisected and embedded.

C-D. Representative largest nodule including tumour to closest deep and lateral margins (tumour to closest lateral margin in block D).

3. "TUMOUR FROM LEFT ARM". Specimen received fresh for tumour banking, and consists of an ellipse of skin 43 x 27mm with subcutis to a depth of 25mm. A loose piece of pigmented tissue in jar (10 x 8 x 4mm) taken for tumour banking. On the skin surface is a dark brown centrally ulcerated nodule 20 x 19mm. Margins inked blue. Cut surface shows that the dark brown nodule extends broadly to the disrupted deep inked tissue margin. Tumour also focally abuts the peripheral margin.

A. Full face of tumour showing skin to disrupted deep tissue margin.

MICROSCOPIC REPORT

1. "TUMOUR FROM LEFT THIGH". The sections show a large circumscribed dermal and subcutaneous deposit of metastatic malignant melanoma. There is surface ulceration and very focal epidermal invasion. The tumour is composed of pleomorphic epithelioid cells with cytoplasmic pigment and a mitotic rate of approximately 1 per mm². There is focal necrosis. The tumour appears clear of the margins, it is 0.8mm to closest (lateral soft tissue) margin.

Printed:

[page 2 of 2]
Requested by:

Accession:

HISTOPATHOLOGY REPORT

2. "TUMOUR FROM LEFT AXILLA". The sections show a large circumscribed dermal and subcutaneous deposit of metastatic malignant melanoma. There is surface ulceration and very focal epidermal invasion. The tumour is composed of pleomorphic epithelioid cells with cytoplasmic pigment and a mitotic rate of approximately 1 per mm². There is focal necrosis. The tumour abuts the lateral and deep soft tissue margins.

3. "TUMOUR FROM LEFT ARM". The sections show a large circumscribed dermal and subcutaneous deposit of metastatic malignant melanoma. There is surface ulceration and very focal epidermal invasion. The tumour is composed of pleomorphic epithelioid cells with cytoplasmic pigment and a mitotic rate of approximately 1 per mm². There is focal necrosis. the tumour is transected by the lateral and deep resection margins.

SUMMARY

1. "TUMOUR FROM LEFT THIGH" - metastatic malignant melanoma, clear margins.
/
2. "TUMOUR FROM LEFT AXILLA" - metastatic malignant melanoma, involved margins.
/
3. "TUMOUR FROM LEFT ARM"- metastatic malignant melanoma, involved margins.

REPORTED BY: Dr.

Printed:

Source: NCI Genomic Data Commons file 0bf1c095-03d5-4c80-92a3-e18b33a76774 (TCGA-EE-A182.FE5C64E4-A121-41C9-BB33-1894105A4DE1.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).